CPTAC case C3L-05386 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/441b356e-c446-44ff-905b-9b3d7a909542

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1977; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 41.9 years (15,315 days); Year of diagnosis: 2018; Days to last known disease status: 1,000 days (2.7 years); Progression or recurrence: no; Days to last follow up: 1,000 days (2.7 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Stem Cell Transplantation, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 374 days (1.0 years); Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 734 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,000 days (2.7 years); Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,006 days (2.8 years); Karnofsky performance status: 70; ECOG performance status: 1.

Other clinical attributes
- Weight: 112.4 kg; Height: 168.2 cm; BMI: 39.73.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-05386-50, C3L-05386-51, C3L-05386-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-05386-54, C3L-05386-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Time between excision and freezing: 58 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
